Somatic mutation profile of tumor specimen 0DT9NS from CCDI case PBCJKW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.9 years (6,901 days).
Specimen 0DT9NS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ef3c1c-d101-4dc1-b995-9009246dd037.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9NG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d586b27-cfee-468b-97fd-be042ab8a49f

The open-access MAF lists 237 somatic variants for this specimen: 122 protein-altering or splice-affecting, 49 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 49, Intron 36, 5'UTR 16, 3'UTR 9, Nonsense Mutation 6, Splice Region 4, Frame Shift Ins 4, Frame Shift Del 3, In Frame Del 2, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDR | c.1444T>C p.C482R | Missense Mutation (SNP) | VAF 258/339 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34231037, CM087498, COSV55778415; ClinVar: risk factor / likely benign; called by muse, mutect2, varscan2
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 138/461 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 134/241 reads (56%) | catalogued as rs1555993345, CM950856, COSV58519797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.3425T>C p.M1142T | Missense Mutation (SNP) | VAF 147/472 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs778878523, CM012442; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TPSD1 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 104/733 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs3865205, COSV52973780; called by muse, varscan2
- A2ML1 | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs201979319; called by muse, mutect2, varscan2
- ADCY5 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs374131018; called by muse, mutect2, varscan2
- ALDOC | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 241/659 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs142754133; called by muse, mutect2, varscan2
- AMZ1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 180/299 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs372160971; called by muse, mutect2, varscan2
- ARMC4 | c.571T>C p.S191P | Missense Mutation (SNP) | VAF 97/255 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs11599060; called by muse, mutect2, varscan2
- ARPP21 | c.1964G>T p.R655L | Missense Mutation (SNP) | VAF 131/220 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761270285, COSV51800417; called by muse, mutect2, varscan2
- ASPRV1 | c.456G>T p.R152S | Missense Mutation (SNP) | VAF 192/480 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs199781771; called by muse, mutect2, varscan2
- ATXN2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 192/466 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1419713183; called by muse, mutect2, varscan2
- C16orf96 | c.3076G>A p.V1026M | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370918237; called by muse, mutect2, varscan2
- C7orf31 | c.968_969del p.P323Rfs*39 | Frame Shift Del (DEL) | VAF 116/244 reads (48%) | catalogued as rs750922176; called by mutect2, pindel, varscan2
- CABIN1 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 190/359 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs193920999, COSV54079534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPERD | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs189734613; called by muse, mutect2, varscan2
- CHTF18 | c.1910A>G p.H637R | Missense Mutation (SNP) | VAF 144/453 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs199809632; called by muse, mutect2, varscan2
- CLK3 | c.978-4C>A | Splice Region (SNP) | VAF 78/209 reads (37%) | catalogued as rs895666393; called by muse, mutect2, varscan2
- CNTN5 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 126/490 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1279173094, COSV99671333; called by muse, varscan2
- CRYBG2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 104/181 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs767259243, COSV100366840; called by muse, mutect2, varscan2
- DCHS1 | c.5953A>G p.T1985A | Missense Mutation (SNP) | VAF 162/466 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as rs200970279; called by muse, mutect2, varscan2
- DDN | c.1464T>G p.D488E | Missense Mutation (SNP) | VAF 172/395 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs775196621; called by muse, mutect2, varscan2
- DLGAP1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 177/499 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs755948170, COSV59787126; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1397A>G p.H466R | Missense Mutation (SNP) | VAF 135/393 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.614); catalogued as rs764599359; called by muse, mutect2, varscan2
- FBXW11 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 104/355 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs778952501; called by muse, mutect2, varscan2
- GADD45A | c.45-6G>C | Splice Region (SNP) | VAF 62/132 reads (47%) | catalogued as rs768317163; called by muse, mutect2, varscan2
- GGNBP2 | c.93G>A p.T31= | Splice Region (SNP) | VAF 71/177 reads (40%) | catalogued as rs1478473061; called by muse, mutect2, varscan2
- GMDS | c.1031A>C p.N344T | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs764254067; called by muse, mutect2, varscan2
- GOLGA6L9 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 6/281 reads (2%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1348789502; called by muse, mutect2
- GPR33 | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 178/420 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1239791895; called by muse, mutect2, varscan2
- GRIA1 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 135/380 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs1404807707; called by muse, mutect2, varscan2
- GSTM1 | c.628T>A p.S210T | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs449856; called by muse, mutect2
- GYG2 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 166/216 reads (77%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs138101249, COSV58549467; ClinVar: likely benign; called by muse, mutect2, varscan2
- HMCN1 | c.3759_3760del p.E1253Dfs*19 | Frame Shift Del (DEL) | VAF 101/361 reads (28%) | catalogued as rs1461614882; called by pindel, varscan2
- INTS7 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 142/349 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs144912933; called by muse, mutect2, varscan2
- KAT2B | c.2465G>A p.S822N | Missense Mutation (SNP) | VAF 125/228 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs149611433; called by muse, mutect2, varscan2
- KCNG2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 186/454 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as rs754867366, COSV60268358; called by muse, varscan2
- KRTAP26-1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 238/634 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as rs1358382221; called by muse, mutect2, varscan2
- LAMB1 | c.4648C>T p.R1550* | Nonsense Mutation (SNP) | VAF 193/574 reads (34%) | catalogued as rs1292231609, COSV55963726; called by muse, mutect2, varscan2
- LRRC52 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 111/302 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs199663208, COSV99673917; called by muse, mutect2, varscan2
- MAN2C1 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1319901236; called by muse, mutect2, varscan2
- MED30 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs200615500; called by muse, mutect2, varscan2
- MLH1 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 163/261 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750760, CM022425, COSV51614892; ClinVar: uncertain significance; called by muse, varscan2
- MMP12 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 114/343 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV58260241; called by muse, mutect2, varscan2
- MSH3 | c.169_195del p.A57_A65del | In Frame Del (DEL) | VAF 111/411 reads (27%) | catalogued as rs762256716; called by pindel, varscan2*
- MTMR6 | c.1492A>G p.M498V | Missense Mutation (SNP) | VAF 138/381 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs536417177; called by muse, mutect2, varscan2
- MUC12 | c.3136C>T p.P1046S (on ENST00000379442; = p.P903S on NM_001164462.1) | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.65); catalogued as rs745358160; called by muse, mutect2
- MUC22 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 180/901 reads (20%) | SIFT tolerated (0.63); catalogued as rs200777418; called by muse, varscan2
- MUC3A | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 176/445 reads (40%) | SIFT deleterious, low confidence (0.02); catalogued as rs1490623108; called by muse, varscan2
- MUC3A | c.1592C>G p.A531G | Missense Mutation (SNP) | VAF 177/446 reads (40%) | SIFT tolerated, low confidence (0.13); catalogued as rs36187473; called by muse, varscan2
- MYH7B | c.2789A>T p.Q930L | Missense Mutation (SNP) | VAF 199/478 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs370253211; called by muse, mutect2, varscan2
- MYOM2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 231/635 reads (36%) | catalogued as rs149520756; called by muse, mutect2, varscan2
- MYRF | c.608G>A p.R203Q (on ENST00000278836 / NM_001127392.3; = p.R194Q on NM_013279.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs767485337; called by muse, mutect2, varscan2
- NBEAL2 | c.4138C>T p.L1380F | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.08); catalogued as rs764151856, COSV52755629; called by muse, mutect2
- NCAN | c.3386C>G p.P1129R | Missense Mutation (SNP) | VAF 134/382 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as rs376485040; called by muse, mutect2, varscan2
- OR10J5 | c.928T>C p.*310Qext*? | Nonstop Mutation (SNP) | VAF 180/486 reads (37%) | catalogued as rs764608472, COSV58387312; called by muse, mutect2, varscan2
- OR13J1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 143/375 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.718); catalogued as rs754660387; called by muse, varscan2
- OR4K15 | c.80A>G p.E27G (on ENST00000305051; = p.E3G on NM_001005486.1) | Missense Mutation (SNP) | VAF 147/408 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs146301798; called by muse, mutect2, varscan2
- OR6C70 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 219/616 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.985); catalogued as rs140433772; called by muse, mutect2, varscan2
- ORMDL2 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 195/448 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs143230663; called by muse, mutect2, varscan2
- PAM | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 128/383 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs201199380; called by muse, mutect2, varscan2
- PAPPA2 | c.3962A>G p.N1321S | Missense Mutation (SNP) | VAF 157/398 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs775641571; called by muse, mutect2, varscan2
- PGAP1 | c.2347C>T p.H783Y | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1201918636; called by muse, mutect2, varscan2
- PKD1 | c.7561C>T p.H2521Y | Missense Mutation (SNP) | VAF 123/325 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs377749451; called by muse, mutect2, varscan2
- PLXNA3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 209/271 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs781795304, COSV100860130; called by muse, mutect2, varscan2
- POM121C | c.3082G>A p.A1028T (on ENST00000607367; = p.A786T on NM_001099415.3) | Missense Mutation (SNP) | VAF 220/537 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs374096282; called by muse, mutect2, varscan2
- POTEM | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as rs201777669, COSV66936014; called by muse, varscan2
- PRKCD | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 127/220 reads (58%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs144572650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRUNE1 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 183/498 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs775047197; called by muse, mutect2, varscan2
- RASSF2 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 170/524 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65081765; called by muse, mutect2, varscan2
- RBP4 | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 119/361 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as rs145044751; called by muse, mutect2, varscan2
- RFESD | c.192A>T p.L64F | Missense Mutation (SNP) | VAF 122/402 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs767559079; called by muse, mutect2, varscan2
- RPS6KC1 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 188/501 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1308433350; called by muse, mutect2, varscan2
- SASH1 | c.3170C>T p.P1057L | Missense Mutation (SNP) | VAF 142/344 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs762732456; called by muse, mutect2, varscan2
- SCAF4 | c.3105G>C p.R1035S | Missense Mutation (SNP) | VAF 179/489 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs138418942, COSV54256306, COSV54257329; called by muse, mutect2, varscan2
- SENP5 | c.41A>C p.H14P | Missense Mutation (SNP) | VAF 176/488 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.497); catalogued as rs764374169; called by muse, mutect2, varscan2
- SLC4A11 | c.2347G>A p.V783M | Missense Mutation (SNP) | VAF 216/611 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs552044097; called by muse, mutect2, varscan2
- SLC4A2 | c.2348G>A p.S783N | Missense Mutation (SNP) | VAF 160/422 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1366290791; called by muse, mutect2, varscan2
- SPTLC3 | c.1621_1622insT p.E541Vfs*4 | Frame Shift Ins (INS) | VAF 156/533 reads (29%) | catalogued as rs1270799333; called by mutect2, pindel, varscan2
- SULF1 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs772711851; called by muse, mutect2, varscan2
- TBCCD1 | c.492+1G>T p.X164_splice | Splice Site (SNP) | VAF 102/324 reads (31%) | catalogued as rs773777385; called by muse, mutect2, varscan2
- TGFBR3 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 166/440 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs139306280, COSV99059590; called by muse, varscan2
- TMEM258 | c.111C>T p.F37= | Splice Region (SNP) | VAF 109/317 reads (34%) | catalogued as rs1565314026, COSV53885663; called by muse, mutect2, varscan2
- TREML1 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs776980813; called by muse, varscan2
- TRIM49C | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as rs1436771167, COSV71510819; called by mutect2, varscan2
- TRPC4AP | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 140/480 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765090147; called by muse, varscan2
- URGCP | c.1294C>T p.R432W (on ENST00000453200 / NM_001077663.3; = p.R423W on NM_017920.4) | Missense Mutation (SNP) | VAF 177/290 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs769879683; called by muse, mutect2, varscan2
- WDR81 | c.4058T>C p.I1353T (on ENST00000409644 / NM_001163809.2; = p.I302T on NM_152348.4) | Missense Mutation (SNP) | VAF 225/589 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.059); catalogued as rs746478142; called by muse, mutect2, varscan2
- WDR93 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 74/211 reads (35%) | catalogued as rs759242280, COSV51532122; called by muse, mutect2, varscan2
- WWC1 | c.2905C>T p.R969W | Missense Mutation (SNP) | VAF 196/552 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs139606423; called by muse, mutect2, varscan2
- YTHDC1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 215/660 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.057); catalogued as rs140009278; called by muse, mutect2, varscan2
- ZAP70 | c.1837A>T p.K613* | Nonsense Mutation (SNP) | VAF 123/315 reads (39%) | catalogued as rs769243855; called by muse, mutect2, varscan2
- ZBTB1 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 214/568 reads (38%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.598); catalogued as rs149197614; called by muse, mutect2, varscan2
- ZBTB11 | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 202/528 reads (38%) | catalogued as rs1185458465, COSV100465491; called by muse, mutect2, varscan2
- ZBTB24 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 202/524 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV57782210; called by muse, mutect2, varscan2
- ZFYVE26 | c.1450C>A p.P484T | Missense Mutation (SNP) | VAF 100/299 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs749761873; called by muse, mutect2, varscan2
- ZNF205 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as rs775487028, COSV54622134; called by muse, mutect2, varscan2
- ZNF492 | c.1312A>G p.K438E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs373260039; called by muse, mutect2
- ZNF587 | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 226/729 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs373357937; called by muse, mutect2, varscan2
- AC104452.1 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ADGRV1 | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 43/610 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- ALK | c.428dup p.E144Gfs*82 | Frame Shift Ins (INS) | VAF 151/527 reads (29%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 106/301 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CD109 | c.4109A>C p.K1370T | Missense Mutation (SNP) | VAF 176/479 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, varscan2
- DDX54 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 133/354 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DIAPH2 | c.2087C>A p.T696N | Missense Mutation (SNP) | VAF 172/225 reads (76%) | SIFT tolerated (0.48); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GALNT3 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 194/565 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GRWD1 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 146/468 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GTF2IRD2 | c.1914G>T p.R638S | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NECTIN3 | c.923A>G p.D308G | Missense Mutation (SNP) | VAF 109/256 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NEK1 | c.2597_2599del p.V866del | In Frame Del (DEL) | VAF 131/445 reads (29%) | called by pindel, varscan2
- NKX3-2 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NOX3 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 173/440 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUMA1 | c.4665dup p.K1556* | Frame Shift Ins (INS) | VAF 73/293 reads (25%) | called by mutect2, pindel, varscan2
- OLFML2B | c.1275_1279dup p.Q427Pfs*19 | Frame Shift Ins (INS) | VAF 45/269 reads (17%) | called by mutect2, pindel, varscan2
- RNF149 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 167/452 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRCIN1 | c.1734C>G p.F578L (on ENST00000621492; = p.F544L on NM_025248.3) | Missense Mutation (SNP) | VAF 148/441 reads (34%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- SYNE1 | c.20827del p.Y6943Tfs*16 (on ENST00000367255 / NM_182961.4; = p.Y6872Tfs*16 on NM_033071.3) | Frame Shift Del (DEL) | VAF 76/337 reads (23%) | called by mutect2, pindel, varscan2
- TGFBR3L | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); called by muse, mutect2
- TPCN1 | c.2053T>C p.F685L | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- WDFY4 | c.1873C>A p.L625M | Missense Mutation (SNP) | VAF 145/371 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF10 | c.3246G>A p.A1082= (on ENST00000398564; = p.A1057= on NM_014629.4) | Silent (SNP) | VAF 173/485 reads (36%) | catalogued as rs150276005; called by muse, mutect2, varscan2
- ATP8B2 | c.2116C>T p.L706= (on ENST00000672630; = p.L673= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 62/508 reads (12%) | catalogued as rs753629164; called by muse, mutect2, varscan2
- C1orf159 | c.429C>T p.R143= (on ENST00000379339 / NM_001330306.2; = p.R107= on NM_017891.5) | Silent (SNP) | VAF 108/168 reads (64%) | catalogued as rs201428293, COSV53880723; called by muse, mutect2, varscan2
- C2CD3 | c.6786G>A p.T2262= | Silent (SNP) | VAF 99/363 reads (27%) | catalogued as rs866076262; called by muse, mutect2, varscan2
- CACHD1 | c.1642T>C p.L548= | Silent (SNP) | VAF 199/602 reads (33%) | catalogued as rs745948856; called by muse, mutect2, varscan2
- CBX4 | c.51G>A p.E17= | Silent (SNP) | VAF 94/246 reads (38%) | catalogued as rs772888287; called by muse, varscan2
- CD320 | c.126C>T p.T42= | Silent (SNP) | VAF 151/241 reads (63%) | catalogued as rs551205813; called by muse, mutect2, varscan2
- CEP126 | c.1701T>C p.H567= | Silent (SNP) | VAF 249/654 reads (38%) | catalogued as COSV99681360; called by muse, mutect2, varscan2
- CNTNAP4 | c.1773G>A p.E591= | Silent (SNP) | VAF 149/366 reads (41%) | catalogued as rs149658030; called by muse, mutect2, varscan2
- DENND6B | c.984C>T p.N328= | Silent (SNP) | VAF 150/271 reads (55%) | catalogued as rs550673289; called by muse, mutect2, varscan2
- DNAH5 | c.5325G>A p.L1775= | Silent (SNP) | VAF 95/323 reads (29%) | catalogued as rs1377939955; called by muse, mutect2, varscan2
- FAM187B | c.774C>A p.L258= | Silent (SNP) | VAF 138/453 reads (30%) | called by muse, mutect2, varscan2
- GAB3 | c.633T>C p.R211= | Silent (SNP) | VAF 165/239 reads (69%) | catalogued as rs782099111, COSV100850677; called by muse, mutect2, varscan2
- GIMAP8 | c.1359G>A p.A453= | Silent (SNP) | VAF 203/609 reads (33%) | catalogued as rs376371559; called by muse, mutect2, varscan2
- GPRIN2 | c.990G>A p.L330= | Silent (SNP) | VAF 145/1088 reads (13%) | catalogued as rs781827224; called by muse, mutect2, varscan2
- GUCY2D | c.1779C>T p.A593= | Silent (SNP) | VAF 23/436 reads (5%) | called by muse, mutect2
- HHLA2 | c.882G>T p.L294= | Silent (SNP) | VAF 181/511 reads (35%) | catalogued as rs185582958; called by muse, mutect2, varscan2
- INTS3 | c.2463G>A p.L821= | Silent (SNP) | VAF 150/380 reads (39%) | catalogued as rs200291183; called by muse, varscan2
- ITSN1 | c.1143G>A p.E381= | Silent (SNP) | VAF 186/482 reads (39%) | catalogued as rs1410225775; called by muse, varscan2
- KCNH1 | c.882G>A p.T294= | Silent (SNP) | VAF 186/415 reads (45%) | catalogued as rs147778651; called by muse, mutect2, varscan2
- KCNH2 | c.1251G>C p.L417= | Silent (SNP) | VAF 170/413 reads (41%) | catalogued as rs1345291709; called by muse, mutect2, varscan2
- KCNK16 | c.714C>A p.I238= | Silent (SNP) | VAF 129/332 reads (39%) | called by muse, varscan2
- KIF16B | c.2334C>A p.L778= | Silent (SNP) | VAF 185/515 reads (36%) | catalogued as rs374151470; called by muse, mutect2, varscan2
- LAMA1 | c.8484C>G p.T2828= | Silent (SNP) | VAF 200/563 reads (36%) | called by muse, mutect2, varscan2
- LGR6 | c.2568C>T p.A856= (on ENST00000367278 / NM_001017403.1; = p.A804= on NM_021636.3) | Silent (SNP) | VAF 138/359 reads (38%) | catalogued as rs769615485; called by muse, mutect2, varscan2
- LRP1 | c.12939G>A p.E4313= | Silent (SNP) | VAF 220/598 reads (37%) | catalogued as rs772155108; called by muse, mutect2, varscan2
- LTV1 | c.807A>G p.Q269= | Silent (SNP) | VAF 99/306 reads (32%) | catalogued as rs753891383; called by muse, mutect2, varscan2
- MUC5AC | c.5883T>C p.I1961= | Silent (SNP) | VAF 36/342 reads (11%) | catalogued as rs1461033952; called by muse, mutect2
- NEURL4 | c.2193C>T p.N731= | Silent (SNP) | VAF 242/594 reads (41%) | catalogued as rs374754333; called by muse, mutect2, varscan2
- NFE2L3 | c.1506A>G p.L502= | Silent (SNP) | VAF 225/433 reads (52%) | catalogued as rs908541485; called by muse, mutect2, varscan2
- NUTM2A | c.2631C>T p.S877= | Silent (SNP) | VAF 53/308 reads (17%) | catalogued as rs1441796963; called by muse, mutect2
- PAPOLA | c.588A>G p.R196= | Silent (SNP) | VAF 125/395 reads (32%) | catalogued as rs1362967247; called by muse, mutect2, varscan2
- PCDHA7 | c.693G>C p.T231= | Silent (SNP) | VAF 108/522 reads (21%) | catalogued as rs530634424; called by muse, mutect2, varscan2
- PDE4DIP | c.78C>T p.I26= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs147804991; called by mutect2, varscan2
- PFKFB3 | c.1038G>A p.A346= | Silent (SNP) | VAF 87/265 reads (33%) | catalogued as rs372499415; called by muse, mutect2, varscan2
- PLIN4 | c.2013T>G p.G671= (on ENST00000301286; = p.G686= on NM_001367868.2) | Silent (SNP) | VAF 119/293 reads (41%) | called by muse, mutect2, varscan2
- POU6F1 | c.810C>T p.T270= | Silent (SNP) | VAF 131/402 reads (33%) | catalogued as rs542080450; called by muse, mutect2, varscan2
- PPIG | c.1422T>C p.D474= | Silent (SNP) | VAF 238/618 reads (39%) | catalogued as rs1455335785; called by muse, mutect2, varscan2
- PRAMEF27 | c.484C>T p.L162= | Silent (SNP) | VAF 17/36 reads (47%) | called by mutect2, varscan2
- PRG4 | c.324T>C p.H108= | Silent (SNP) | VAF 137/419 reads (33%) | catalogued as rs1357035287; called by muse, mutect2, varscan2
- RGMB | c.1047C>T p.Y349= (on ENST00000513185 / NM_001366508.1; = p.Y390= on NM_001012761.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 150/387 reads (39%) | catalogued as rs377028475; called by muse, mutect2, varscan2
- RPRD2 | c.1809A>T p.S603= | Silent (SNP) | VAF 141/432 reads (33%) | called by muse, mutect2, varscan2
- SLC4A2 | c.2209C>T p.L737= | Silent (SNP) | VAF 238/642 reads (37%) | catalogued as rs1422877147; called by muse, mutect2
- SPTBN4 | c.2544G>A p.L848= | Silent (SNP) | VAF 141/369 reads (38%) | catalogued as rs748715100; called by muse, mutect2, varscan2
- SRGAP2C | c.636C>T p.N212= | Silent (SNP) | VAF 47/310 reads (15%) | catalogued as rs201138873; called by muse, mutect2, varscan2
- TEAD2 | c.744G>A p.R248= | Silent (SNP) | VAF 71/203 reads (35%) | catalogued as rs373092673; called by muse, mutect2, varscan2
- TIMM10 | c.57C>T p.A19= | Silent (SNP) | VAF 117/387 reads (30%) | catalogued as rs749069226, COSV57201759; called by muse, mutect2, varscan2
- TMC1 | c.2283A>G p.*761= | Silent (SNP) | VAF 180/476 reads (38%) | catalogued as rs766103436; called by muse, varscan2
- XAB2 | c.510G>A p.R170= | Silent (SNP) | VAF 115/198 reads (58%) | catalogued as rs780766793; called by muse, mutect2, varscan2
- ADAMTS10 | c.1588-105_1588-93delinsCTTCCAGCCCCATCCCGGAGAGGCTGATATC | Intron (INS) | VAF 21/73 reads (29%) | called by pindel, varscan2*
- AFDN | chr6:167976349 G>A | 3'Flank (SNP) | VAF 110/778 reads (14%) | catalogued as rs762609622; called by muse, varscan2
- AMDHD2 | c.*1539_*1575delinsG | 3'UTR (DEL) | VAF 45/125 reads (36%) | called by pindel, varscan2*
- ANKRD33 | c.122-34C>G | Intron (SNP) | VAF 156/330 reads (47%) | catalogued as rs764553468; called by muse, mutect2, varscan2
- AP2A1 | c.2114+97C>T | Intron (SNP) | VAF 45/91 reads (49%) | catalogued as rs767193598; called by muse, mutect2, varscan2
- ATP6V1G1 | c.-40G>C | 5'UTR (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- CARMIL3 | c.-45G>A | 5'UTR (SNP) | VAF 49/150 reads (33%) | catalogued as rs1207129424; called by muse, mutect2, varscan2
- CDH15 | c.358-99G>A | Intron (SNP) | VAF 50/145 reads (34%) | catalogued as rs561144959; called by muse, mutect2, varscan2
- CLDN16 | c.-46_-45delinsC | 5'UTR (DEL) | VAF 117/797 reads (15%) | catalogued as rs386669518; called by pindel, varscan2*
- CROCC | c.*70C>A | 3'UTR (SNP) | VAF 48/72 reads (67%) | catalogued as rs555547135; called by mutect2, varscan2
- CTRB2 | c.496+57C>T | Intron (SNP) | VAF 55/206 reads (27%) | catalogued as rs998198086; called by muse, varscan2
- CTU2 | c.344-155G>T | Intron (SNP) | VAF 177/537 reads (33%) | catalogued as rs750877962; called by muse, mutect2, varscan2
- DHRS2 | c.489-78A>G | Intron (SNP) | VAF 23/61 reads (38%) | catalogued as rs949467218; called by muse, mutect2, varscan2
- DMXL2 | c.8461-90T>A | Intron (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- EPS8L2 | c.557+72_557+76delinsCGGCAGGGA | Intron (INS) | VAF 41/105 reads (39%) | called by pindel, varscan2*
- ERVV-2 | c.-32T>C | 5'UTR (SNP) | VAF 36/242 reads (15%) | catalogued as rs113173812; called by muse, varscan2
- FAM71C | c.-12_-11delinsA | 5'UTR (DEL) | VAF 226/485 reads (47%) | catalogued as rs386765697, COSV60942620; called by pindel, varscan2*
- FANCG | c.-100G>T | 5'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as rs570546906; called by muse, mutect2, varscan2
- GOLGA6L3 | n.1017G>A | RNA (SNP) | VAF 33/211 reads (16%) | catalogued as rs202117168; called by muse, mutect2, varscan2
- HSPB7 | c.*84C>T | 3'UTR (SNP) | VAF 56/102 reads (55%) | catalogued as rs926563866; called by muse, mutect2, varscan2
- IDE | c.1884+588_1884+589del | Intron (DEL) | VAF 124/499 reads (25%) | called by pindel, varscan2
- IFIH1 | c.623-58A>G | Intron (SNP) | VAF 37/126 reads (29%) | catalogued as rs1446296286; called by muse, mutect2, varscan2
- IL11RA | c.1170-88C>T | Intron (SNP) | VAF 78/189 reads (41%) | catalogued as rs1257587956; called by muse, mutect2, varscan2
- IL4 | c.136-11C>G | Intron (SNP) | VAF 122/300 reads (41%) | called by muse, mutect2, varscan2
- JAG1 | c.2917-29C>T | Intron (SNP) | VAF 148/320 reads (46%) | catalogued as rs749716879; called by muse, mutect2, varscan2
- KIAA0040 | c.-189C>A | 5'UTR (SNP) | VAF 92/328 reads (28%) | catalogued as rs3208835, COSV70593789; called by muse, varscan2
- LAMA4 | c.*14A>G | 3'UTR (SNP) | VAF 162/422 reads (38%) | catalogued as rs782115194; called by muse, mutect2, varscan2
- LEPR | c.2674-3014_2674-3013insA | Intron (INS) | VAF 110/393 reads (28%) | called by mutect2, pindel, varscan2
- LRRC27 | chr10:132331819 C>G | 5'Flank (SNP) | VAF 22/58 reads (38%) | catalogued as rs749447423; called by muse, varscan2
- MAGI2 | c.418+11T>C | Intron (SNP) | VAF 100/277 reads (36%) | catalogued as rs752292799; called by muse, mutect2, varscan2
- MAPKAPK2 | c.1059+111C>T | Intron (SNP) | VAF 106/299 reads (35%) | catalogued as rs1302633509; called by muse, mutect2, varscan2
- MEST | c.535+14C>T | Intron (SNP) | VAF 113/331 reads (34%) | catalogued as rs375635223; called by muse, mutect2, varscan2
- MTBP | c.-29C>G | 5'UTR (SNP) | VAF 117/355 reads (33%) | catalogued as rs372865507; called by muse, mutect2, varscan2
- OBSL1 | c.-42del | 5'UTR (DEL) | VAF 16/110 reads (15%) | catalogued as rs757193063, COSV54725669; ClinVar: likely benign; called by mutect2, pindel
- OR10AC1 | chr7:143522585 G>A | 5'Flank (SNP) | VAF 175/280 reads (63%) | catalogued as rs2966696; called by muse, mutect2, varscan2
- PAQR3 | c.*126-64T>A | Intron (SNP) | VAF 35/102 reads (34%) | catalogued as rs76033792; called by muse, varscan2
- PAQR3 | c.*126-65A>T | Intron (SNP) | VAF 34/100 reads (34%) | catalogued as rs76520492; called by muse, varscan2
- PKD1 | c.12444+17G>A | Intron (SNP) | VAF 86/285 reads (30%) | catalogued as rs371749301; called by muse, mutect2, varscan2
- PKP2 | c.*83A>G | 3'UTR (SNP) | VAF 77/230 reads (33%) | catalogued as rs543423631, COSV99298230; called by muse, mutect2, varscan2
- POGLUT2 | c.846-55C>G | Intron (SNP) | VAF 77/215 reads (36%) | called by muse, mutect2, varscan2
- PPP5D1 | n.588+64C>T | Intron (SNP) | VAF 42/104 reads (40%) | catalogued as rs770439536; called by muse, mutect2, varscan2
- PROSER1 | c.275+28_275+35delinsACTTCA | Intron (DEL) | VAF 6/48 reads (13%) | called by pindel, varscan2*
- PSMB10 | c.-23del | 5'UTR (DEL) | VAF 49/187 reads (26%) | catalogued as rs770710099; called by mutect2, pindel, varscan2
- PTAR1 | c.-67C>G | 5'UTR (SNP) | VAF 29/78 reads (37%) | catalogued as rs1435253711; called by muse, mutect2, varscan2
- PTPRC | c.3645+14A>T | Intron (SNP) | VAF 108/296 reads (36%) | catalogued as rs199753199; called by muse, mutect2, varscan2
- RAPGEF1 | c.*38G>A | 3'UTR (SNP) | VAF 97/283 reads (34%) | catalogued as rs371385939; called by muse, mutect2, varscan2
- RND3 | c.-38-19_-38-18delinsATATATA | Intron (INS) | VAF 12/68 reads (18%) | called by pindel, varscan2*
- SCPEP1 | c.-14G>T | 5'UTR (SNP) | VAF 45/161 reads (28%) | catalogued as rs374838899; called by muse, varscan2
- SEC24B | c.-14C>G | 5'UTR (SNP) | VAF 101/318 reads (32%) | called by muse, mutect2, varscan2
- SF1 | c.237-37C>T | Intron (SNP) | VAF 103/252 reads (41%) | catalogued as rs553278015; called by muse, mutect2, varscan2
- SHKBP1 | c.-17C>G | 5'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- SIMC1 | c.-255T>A | 5'UTR (SNP) | VAF 46/460 reads (10%) | catalogued as rs866802577; called by muse, mutect2
- SIMC1 | c.-137+57C>T | Intron (SNP) | VAF 40/173 reads (23%) | catalogued as rs1278494864; called by muse, mutect2, varscan2
- SLC22A11 | c.1058+60G>C | Intron (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2
- SLC38A7 | c.1031+55_1031+64delinsGGATGG | Intron (DEL) | VAF 202/332 reads (61%) | catalogued as rs386791225; called by pindel, varscan2*
- SNX17 | c.-67G>C | 5'UTR (SNP) | VAF 179/501 reads (36%) | catalogued as rs11557230; called by muse, mutect2, varscan2
- SRCAP | c.6609+44C>T | Intron (SNP) | VAF 63/163 reads (39%) | catalogued as rs372140432; called by muse, mutect2, varscan2
- SSPOP | n.9300dup | RNA (INS) | VAF 126/440 reads (29%) | called by pindel, varscan2
- SUCLA2 | c.1028-38G>A | Intron (SNP) | VAF 112/310 reads (36%) | called by muse, mutect2, varscan2
- TEPSIN | c.815+21C>T | Intron (SNP) | VAF 116/324 reads (36%) | catalogued as rs746354969; called by muse, mutect2, varscan2
- THRA | c.1110+211A>C | Intron (SNP) | VAF 47/120 reads (39%) | catalogued as rs925728210; called by muse, mutect2, varscan2
- TIMP2 | c.465+56dup | Intron (INS) | VAF 43/141 reads (30%) | catalogued as rs754234101; called by mutect2, pindel, varscan2
- TRIM44 | c.*11C>T | 3'UTR (SNP) | VAF 96/255 reads (38%) | catalogued as rs765263686; called by muse, varscan2
- TTYH2 | c.129+1995_129+2030delinsGGTAAGTTCCCCTGTTGTGACCACAGGTCTCTCCTG | Intron (ONP) | VAF 67/325 reads (21%) | called by pindel, varscan2*
- UBAC1 | c.*5C>T | 3'UTR (SNP) | VAF 126/309 reads (41%) | catalogued as rs537174908, COSV100873824; called by muse, mutect2, varscan2
- ZSCAN21 | c.*9C>T | 3'UTR (SNP) | VAF 108/276 reads (39%) | catalogued as rs753672951; called by muse, mutect2, varscan2
